Somatic mutation profile of cancer-model specimen HCM-SANG-0299-C15-85A (3D Organoid; aliquot HCM-SANG-0299-C15-85A-01D-A78U-36), derived from the primary tumor of HCMI case HCM-SANG-0299-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS.
Specimen HCM-SANG-0299-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb83c2d4-6c98-4b13-88ae-7b08d838c16c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0299-C15-10B (Blood Derived Normal), aliquot HCM-SANG-0299-C15-10B-01D-A78U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc8077d7-4ee2-4356-a79d-344102fa9087

The open-access MAF lists 144 somatic variants for this specimen: 94 protein-altering or splice-affecting, 30 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 30, Intron 9, Nonsense Mutation 8, 3'UTR 4, RNA 3, Splice Site 2, Splice Region 2, 3'Flank 2, Frame Shift Del 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NEB | c.18348+1G>T p.X6116_splice | Splice Site (SNP) | VAF 7/122 reads (6%) | catalogued as rs1011425121; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 200/201 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AOX1 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.234); catalogued as rs150771380; called by muse, mutect2, varscan2
- AZI2 | c.525G>C p.E175D | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs1387048493; called by muse, mutect2, varscan2
- BNC2 | c.2120G>A p.R707K | Missense Mutation (SNP) | VAF 53/338 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.132); catalogued as rs372768243; called by muse, mutect2, varscan2
- C17orf64 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as rs754589179; called by muse, mutect2, varscan2
- C2CD3 | c.5930G>A p.R1977Q | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775042648; called by muse, mutect2, varscan2
- CCDC136 | c.1606-5C>T | Splice Region (SNP) | VAF 113/208 reads (54%) | catalogued as rs905348863; called by muse, mutect2, varscan2
- CCDC63 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 120/400 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as rs369178253; called by muse, mutect2, varscan2
- CFAP54 | c.7399G>T p.G2467* | Nonsense Mutation (SNP) | VAF 83/112 reads (74%) | catalogued as COSV61574271; called by muse, mutect2, varscan2
- CHRM2 | c.506G>T p.R169I | Missense Mutation (SNP) | VAF 189/376 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57769105; called by muse, mutect2, varscan2
- CILP2 | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 76/228 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs371319583; called by muse, mutect2, varscan2
- CNTNAP5 | c.872A>G p.H291R | Missense Mutation (SNP) | VAF 102/154 reads (66%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as rs755973563; called by muse, mutect2, varscan2
- COL1A2 | c.1490C>A p.P497H | Missense Mutation (SNP) | VAF 105/448 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51964677; called by muse, mutect2, varscan2
- CRAMP1 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 114/115 reads (99%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as rs754112928; called by muse, mutect2, varscan2
- CRHR2 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1286527796, COSV100793233; called by muse, mutect2, varscan2
- CRYBG3 | c.7160G>C p.S2387T | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs768074277, COSV51717501; called by muse, mutect2, varscan2
- DACH1 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 76/76 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as COSV57516881; called by muse, mutect2, varscan2
- DOCK2 | c.2060G>T p.R687L | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.873); catalogued as COSV56981234; called by muse, mutect2
- FLG | c.4214C>G p.S1405* | Nonsense Mutation (SNP) | VAF 37/779 reads (5%) | catalogued as rs1443712053, CM156630, COSV64244138; called by muse, mutect2
- FLG2 | c.258C>A p.N86K | Missense Mutation (SNP) | VAF 73/279 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV66166404; called by muse, mutect2, varscan2
- GBF1 | c.4063G>A p.V1355I (on ENST00000369983 / NM_001377137.1; = p.V1354I on NM_004193.3) | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs141610784; called by muse, mutect2, varscan2
- GPAA1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 75/215 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.643); catalogued as rs782374867; called by muse, mutect2, varscan2
- GRM5 | c.1570C>T p.R524* | Nonsense Mutation (SNP) | VAF 32/136 reads (24%) | catalogued as rs1259002284, COSV59616743; called by muse, mutect2, varscan2
- GRM5 | c.596C>A p.A199E | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59597978; called by muse, mutect2, varscan2
- HCK | c.1420T>C p.Y474H | Missense Mutation (SNP) | VAF 125/377 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1180089596; called by muse, mutect2, varscan2
- HSPG2 | c.9695G>A p.R3232H | Missense Mutation (SNP) | VAF 113/404 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs758945882, COSV104424664; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KAT2B | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 111/222 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs1205273470, COSV55434569; called by muse, mutect2, varscan2
- KAT6A | c.5351T>G p.V1784G | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.996); catalogued as COSV55904384, COSV99704330; called by muse, mutect2, varscan2
- KIR3DL3 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 149/396 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1277875430, COSV52550084; called by muse, mutect2, varscan2
- LNPEP | c.435C>A p.N145K | Missense Mutation (SNP) | VAF 76/160 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs758200052, COSV51481596; called by muse, mutect2, varscan2
- MRC2 | c.4129G>A p.G1377R | Missense Mutation (SNP) | VAF 148/310 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200529475; called by muse, mutect2, varscan2
- MYLK4 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 140/214 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs757508603, COSV99193684; called by muse, mutect2, varscan2
- NOSTRIN | c.454C>A p.Q152K (on ENST00000317647 / NM_001039724.4; = p.Q74K on NM_052946.3) | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV100474007; called by muse, mutect2
- PDE1C | c.1460G>C p.G487A | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.699); catalogued as COSV58503226; called by muse, mutect2, varscan2
- PREX2 | c.141G>A p.S47= | Splice Region (SNP) | VAF 118/505 reads (23%) | catalogued as COSV55800780; called by muse, mutect2, varscan2
- PRX | c.932G>T p.C311F | Missense Mutation (SNP) | VAF 41/402 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV52529588; called by muse, mutect2, varscan2
- PSMD6 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 90/186 reads (48%) | catalogued as rs1351129846; called by muse, mutect2, varscan2
- RGS12 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT tolerated (0.66); PolyPhen benign (0.028); catalogued as rs545165653, COSV60902115; called by muse, mutect2, varscan2
- RIMBP2 | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 125/367 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs370841973; called by muse, mutect2, varscan2
- RYR3 | c.4981C>T p.L1661F | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101212945; called by muse, mutect2, varscan2
- SMCHD1 | c.2288C>T p.S763L | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV55250956, COSV55263008; called by muse, mutect2, varscan2
- SPTBN5 | c.4816G>A p.G1606S | Missense Mutation (SNP) | VAF 193/397 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.266); catalogued as rs1456048646; called by muse, mutect2, varscan2
- ZNF107 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.039); catalogued as rs746749106; called by muse, mutect2, varscan2
- ZNF300 | c.104A>T p.D35V | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs764933049; called by muse, mutect2, varscan2
- ZNF474 | c.353A>C p.Q118P | Missense Mutation (SNP) | VAF 75/157 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV56946005; called by muse, mutect2, varscan2
- ZSCAN1 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.302); catalogued as COSV56608522; called by muse, mutect2
- ADAM29 | c.946G>C p.V316L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ADAMTS17 | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 265/266 reads (100%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- ARID1A | c.266_269del p.G89Afs*11 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- ARTN | c.595A>T p.M199L (on ENST00000372354; = p.M207L on NM_057090.2) | Missense Mutation (SNP) | VAF 85/300 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- BGN | c.239-1G>A p.X80_splice | Splice Site (SNP) | VAF 52/52 reads (100%) | called by muse, mutect2, varscan2
- BIRC6 | c.8545G>T p.E2849* | Nonsense Mutation (SNP) | VAF 51/118 reads (43%) | called by muse, mutect2, varscan2
- C12orf42 | c.154C>A p.P52T | Missense Mutation (SNP) | VAF 73/109 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- CABS1 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 54/145 reads (37%) | called by muse, mutect2, varscan2
- CATSPER2 | c.1277C>A p.S426* (on ENST00000321596 / NM_001282309.3; = p.S428* on NM_172095.4) | Nonsense Mutation (SNP) | VAF 21/298 reads (7%) | called by muse, mutect2
- CDT1 | c.851_871del p.P284_R290del | In Frame Del (DEL) | VAF 57/256 reads (22%) | called by mutect2, pindel, varscan2
- CEP164 | c.2739G>T p.L913F | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CLNK | c.953C>A p.A318E | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.011); called by muse, mutect2
- DENND1B | c.1644G>C p.E548D | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DOCK2 | c.4412C>A p.T1471N | Missense Mutation (SNP) | VAF 7/190 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPDR1 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 26/421 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2
- FAM13C | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- FBXO38 | c.3110C>T p.P1037L (on ENST00000340253 / NM_205836.3; = p.P962L on NM_030793.5) | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- GABRG1 | c.1232A>T p.D411V | Missense Mutation (SNP) | VAF 120/397 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- IKZF2 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMP5 | c.451A>C p.T151P | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- MKRN1 | c.784G>T p.A262S | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2
- NEDD9 | c.62A>T p.E21V | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OLFM2 | c.1099A>C p.K367Q | Missense Mutation (SNP) | VAF 38/576 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR10A7 | c.599T>G p.L200R | Missense Mutation (SNP) | VAF 106/376 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- OSGIN2 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PACS1 | c.1586C>T p.S529F | Missense Mutation (SNP) | VAF 76/701 reads (11%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- PCYOX1 | c.1475T>C p.I492T | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- PDZRN4 | c.105C>G p.H35Q | Missense Mutation (SNP) | VAF 348/698 reads (50%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- PLSCR5 | c.366G>T p.R122S | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- POU3F1 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 97/349 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- PTGER3 | c.1180C>A p.L394M | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- RAB3GAP1 | c.164C>G p.S55C | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- REXO4 | c.646G>C p.A216P | Missense Mutation (SNP) | VAF 115/284 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- RP1 | c.5074A>G p.M1692V | Missense Mutation (SNP) | VAF 33/807 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RTL9 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 121/121 reads (100%) | SIFT tolerated (0.27); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SIK2 | c.2365C>G p.P789A | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SIPA1L1 | c.1994C>T p.T665I | Missense Mutation (SNP) | VAF 60/112 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, varscan2
- SLCO1B1 | c.76G>T p.G26* | Nonsense Mutation (SNP) | VAF 120/120 reads (100%) | called by muse, mutect2, varscan2
- SMG9 | c.833T>G p.I278S | Missense Mutation (SNP) | VAF 128/283 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- SOHLH1 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 198/532 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SORL1 | c.1561T>C p.Y521H | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- UBQLNL | c.292T>G p.L98V | Missense Mutation (SNP) | VAF 76/149 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- UNC79 | c.4331C>T p.A1444V (on ENST00000393151 / NM_001346218.2; = p.A1267V on NM_020818.5) | Missense Mutation (SNP) | VAF 85/186 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZNF19 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 119/119 reads (100%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF223 | c.577A>G p.I193V | Missense Mutation (SNP) | VAF 118/254 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2
- ZNF493 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.664); called by muse, varscan2
- ZNF493 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); called by muse, varscan2
- ABCB5 | c.2958G>A p.A986= (on ENST00000404938 / NM_001163941.2; = p.A541= on NM_178559.6) | Silent (SNP) | VAF 70/150 reads (47%) | catalogued as rs773480139, COSV51706119; called by muse, mutect2, varscan2
- AURKC | c.405C>T p.S135= (on ENST00000302804 / NM_001015878.2; = p.S101= on NM_003160.3) | Silent (SNP) | VAF 44/669 reads (7%) | catalogued as rs141028635; called by muse, mutect2
- CAPN13 | c.1860C>T p.S620= | Silent (SNP) | VAF 109/290 reads (38%) | catalogued as rs201127772; called by muse, mutect2, varscan2
- CNTN6 | c.2923A>C p.R975= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs755233831, COSV100610613, COSV63189798; called by muse, mutect2, varscan2
- CSMD1 | c.5379C>T p.N1793= (on ENST00000520002; = p.N1792= on NM_033225.6) | Silent (SNP) | VAF 135/304 reads (44%) | catalogued as rs769926696; called by muse, mutect2, varscan2
- CTSG | c.414C>T p.P138= | Silent (SNP) | VAF 137/277 reads (49%) | called by muse, mutect2, varscan2
- DLK1 | c.309C>T p.C103= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as rs776829791; called by muse, mutect2, varscan2
- ENTPD4 | c.1689C>T p.N563= | Silent (SNP) | VAF 111/458 reads (24%) | catalogued as rs376644779; called by muse, mutect2, varscan2
- GPCPD1 | c.537C>G p.L179= | Silent (SNP) | VAF 191/290 reads (66%) | catalogued as COSV66830428; called by muse, mutect2, varscan2
- HMCN1 | c.10548C>T p.S3516= | Silent (SNP) | VAF 31/169 reads (18%) | called by muse, mutect2, varscan2
- IRF7 | c.192C>T p.D64= (on ENST00000397566; = p.D51= on NM_001572.5) | Silent (SNP) | VAF 93/192 reads (48%) | called by muse, mutect2, varscan2
- JSRP1 | c.633C>T p.D211= | Silent (SNP) | VAF 133/457 reads (29%) | catalogued as COSV55554028; called by muse, mutect2, varscan2
- MAP1B | c.1386G>A p.P462= | Silent (SNP) | VAF 83/174 reads (48%) | catalogued as rs368021857; called by muse, mutect2, varscan2
- MYRIP | c.1338C>A p.P446= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- OPCML | c.987T>G p.A329= | Silent (SNP) | VAF 129/194 reads (66%) | catalogued as rs1424119894, COSV59409651, COSV59428469; called by muse, mutect2, varscan2
- PLP1 | c.348G>A p.T116= | Silent (SNP) | VAF 10/236 reads (4%) | called by muse, mutect2
- PPEF2 | c.1230C>T p.T410= | Silent (SNP) | VAF 72/217 reads (33%) | catalogued as rs754840987, COSV54421172; called by muse, mutect2, varscan2
- PRAMEF7 | c.1218A>T p.L406= | Silent (SNP) | VAF 31/1230 reads (3%) | called by muse, mutect2
- PRDM12 | c.507C>T p.N169= | Silent (SNP) | VAF 92/207 reads (44%) | catalogued as rs369430134; called by muse, varscan2
- PRDM9 | c.12A>G p.E4= | Silent (SNP) | VAF 136/298 reads (46%) | called by muse, mutect2, varscan2
- RDH13 | c.780G>A p.L260= (on ENST00000415061 / NM_001145971.2; = p.L189= on NM_138412.4) | Silent (SNP) | VAF 33/116 reads (28%) | catalogued as rs1282023012; called by muse, mutect2, varscan2
- RNF217 | c.522C>T p.P174= | Silent (SNP) | VAF 142/214 reads (66%) | catalogued as rs752110814; called by muse, mutect2, varscan2
- SKOR2 | c.408G>A p.P136= | Silent (SNP) | VAF 63/523 reads (12%) | called by muse, mutect2, varscan2
- TBL3 | c.969C>T p.S323= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as COSV100224666; called by muse, mutect2, varscan2
- TRAV26-2 | c.165G>A p.Q55= | Silent (SNP) | VAF 89/183 reads (49%) | catalogued as rs1198540441; called by muse, mutect2, varscan2
- TSG101 | c.12G>A p.S4= | Silent (SNP) | VAF 75/174 reads (43%) | called by muse, mutect2, varscan2
- TTC6 | c.1212A>C p.G404= | Silent (SNP) | VAF 39/188 reads (21%) | called by muse, mutect2, varscan2
- ULK1 | c.2118G>A p.A706= | Silent (SNP) | VAF 40/180 reads (22%) | catalogued as rs768265590; called by muse, mutect2
- UTRN | c.7503C>A p.A2501= | Silent (SNP) | VAF 33/92 reads (36%) | called by muse, mutect2, varscan2
- ZAR1 | c.699G>A p.A233= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as rs1262970999; called by muse, mutect2, varscan2
- AC132807.2 | n.88A>C | RNA (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846185 G>C | 5'Flank (SNP) | VAF 215/217 reads (99%) | called by muse, mutect2, varscan2
- ARRDC3 | c.*14T>C | 3'UTR (SNP) | VAF 41/85 reads (48%) | called by muse, mutect2, varscan2
- CALY | c.361-189G>A | Intron (SNP) | VAF 48/98 reads (49%) | called by muse, mutect2, varscan2
- CMTM3 | c.400-87G>T | Intron (SNP) | VAF 93/197 reads (47%) | catalogued as COSV100411870; called by muse, mutect2, varscan2
- COL18A1 | c.3972+37G>T | Intron (SNP) | VAF 62/233 reads (27%) | catalogued as rs773830583; called by muse, mutect2, varscan2
- ETHE1 | c.*15G>T | 3'UTR (SNP) | VAF 255/499 reads (51%) | called by muse, mutect2, varscan2
- FAM20C | c.864-17892G>T | Intron (SNP) | VAF 45/373 reads (12%) | called by muse, mutect2, varscan2
- FAM230J | n.747_773del | RNA (DEL) | VAF 0/1 reads (0%) | catalogued as rs758166610; called by mutect2, varscan2*
- GUSBP1 | n.180-10226G>A | Intron (SNP) | VAF 114/1810 reads (6%) | catalogued as rs1316511041; called by muse, mutect2
- KRT7 | chr12:52253746 G>A | 3'Flank (SNP) | VAF 79/251 reads (31%) | catalogued as rs776317807; called by muse, mutect2, varscan2
- MGAM | c.4619-13739G>T | Intron (SNP) | VAF 26/217 reads (12%) | called by muse, mutect2, varscan2
- PRDM11 | chr11:45227093 G>A | 3'Flank (SNP) | VAF 136/302 reads (45%) | catalogued as rs780830634; called by muse, mutect2, varscan2
- RNF220 | c.907-145G>A | Intron (SNP) | VAF 43/178 reads (24%) | catalogued as rs761814515; called by muse, mutect2, varscan2
- SPATA31C1 | n.3675G>A | RNA (SNP) | VAF 96/568 reads (17%) | catalogued as rs765471252; called by muse, mutect2, varscan2
- STMND1 | c.82-4118C>A | Intron (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- TCEA2 | c.*45C>T | 3'UTR (SNP) | VAF 13/29 reads (45%) | catalogued as rs767666489; called by muse, mutect2, varscan2
- TYW1B | c.-27C>T | 5'UTR (SNP) | VAF 70/366 reads (19%) | catalogued as rs1486712742, COSV101328401; called by muse, mutect2, varscan2
- XIAP | c.*6520T>G | 3'UTR (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- YPEL2 | c.117+170A>T | Intron (SNP) | VAF 21/99 reads (21%) | catalogued as rs987726765; called by muse, mutect2, varscan2
